Gene-level copy-number profile of specimen HCM-BROD-0758-C43-85N from HCMI case HCM-BROD-0758-C43, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 55.3 years (20,195 days).
Specimen HCM-BROD-0758-C43-85N: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 8.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file fd761ef1-e16c-42e9-b604-b4d5db23450b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0758-C43-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,238 have no estimate.
https://portal.gdc.cancer.gov/files/8e2eda3a-3eed-41b4-8779-5ba2071adccc

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 725; copy number 2: 10,345; copy number 3: 22,140; copy number 4: 17,099; copy number 5: 2,432; copy number 6: 2,948; copy number 7: 364; copy number 8: 1,494; copy number 9: 304; copy number 10: 268; copy number 11: 88; copy number 12: 2; copy number 13: 84; copy number 14: 32; copy number 19: 59; copy number 26: 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,560 genes in 25 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:2,315,040–2,413,797, 7 genes, copy number 7: AL590822.3, MORN1, AL589739.1, AL513477.1, AL513477.2, RER1, PEX10.
- chr1:2,811,850–2,817,767, 3 genes, copy number 7: AL592464.2, AL592464.3, AL592464.1.
- chr1:20,186,096–20,244,664, 2 genes, copy number 7: UBXN10, LINC01757.
- chr1:20,482,391–20,526,751, 3 genes, copy number 7: CAMK2N1, MUL1, RPS4XP4.
- chr3:40,970,541–43,691,594, 61 genes, copy number 8 (within-gene range 3–8) (broad region; genes not listed).
- chr7:126,438,598–127,253,093, 2 genes, copy number 7 (within-gene range 6–7): GRM8, AC002057.2.
- chr7:126,533,665–151,520,120, 637 genes, copy number 7–10 (within-gene range 6–10) (broad region; genes not listed).
- chr12:51,815,043–52,108,261, 17 genes, copy number 11: AC068987.2, FIGNL2, AC068987.3, FIGNL2-DT, ANKRD33, AC025259.2, ACVRL1, ACVR1B, RNU6-574P, TAMALIN, NR4A1, NR4A1AS, ATG101, AC025259.1, SMIM41, OR7E47P, AC078864.1.
- chr12:56,101,331–56,360,167, 28 genes, copy number 13 (within-gene range 3–13): AC034102.2, PA2G4, AC034102.4, RPL41, ESYT1, ZC3H10, AC034102.7, AC034102.6, AC034102.5, MYL6B, MYL6, SMARCC2, AC073896.4, RNF41, NABP2, SLC39A5, ANKRD52, COQ10A, AC073896.5, CS, AC073896.1, AC073896.2, AC073896.3, CNPY2, PAN2, IL23A, STAT2, RNU7-40P.
- chr12:57,434,784–60,269,686, 71 genes, copy number 14–19 (broad region; genes not listed).
- chr12:68,575,858–68,687,755, 6 genes, copy number 7 (within-gene range 5–14): Metazoa_SRP, RAP1B, RPL10P12, SNORA70G, ATP5PDP4, AC090061.1.
- chr12:68,686,951–69,579,793, 24 genes, copy number 10–14 (within-gene range 7–14): NUP107, KRT8P39, SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1, AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2.
- chr12:83,661,009–84,449,878, 4 genes, copy number 7: AC093025.1, AC090679.2, AC090679.1, AC087888.1.
- chr12:101,696,947–102,513,655, 27 genes, copy number 7–8: CHPT1, RNY1P16, SYCP3, GNPTAB, RNU6-101P, AC063950.1, RNA5SP368, RNU6-172P, RNA5SP369, RNU6-1183P, HSPE1P4, DRAM1, AC084398.2, AC084398.1, AC079907.2, NENFP2, WASHC3, AC079907.1, NUP37, PARPBP, PMCH, HELLPAR, RN7SL793P, AC093023.1, LINC02456, IGF1, AC010202.1.
- chr12:104,455,295–104,762,014, 1 gene, copy number 13 (within-gene range 4–13): CHST11.
- chr12:104,591,633–107,912,620, 54 genes, copy number 13–26: MIR3922, SLC41A2, Y_RNA, AC089985.1, KRT18P20, C12orf45, ALDH1L2, WASHC4, APPL2, C12orf75, AC078874.1, KCCAT198, CASC18, ST13P3, AC011595.2, NUAK1, AC011595.1, AC010182.1, CKAP4, AC079174.1, AC079174.2, RNU7-94P, TCP11L2, POLR3B, AC079385.1, RFX4, AC079385.2, AC079385.3, RIC8B, AC007695.1, EEF1B2P4, RPL30P12, AC007541.1, TMEM263, MTERF2, CRY1, AC078929.1, SETP7, BTBD11, AC009774.1, RNA5SP371, AC007540.1, Y_RNA, PWP1, AC007622.1, PRDM4, AC007622.2, ASCL4, AC126177.3, AC126177.5, AC126177.2, AC126177.4, AC126177.6, AC126177.1.
- chr12:114,682,292–118,908,930, 74 genes, copy number 9–12 (within-gene range 4–13) (broad region; genes not listed).
- chr12:119,989,869–121,298,308, 66 genes, copy number 9–11 (broad region; genes not listed).
- chr12:130,396,137–130,716,281, 1 gene, copy number 8 (within-gene range 5–8): RIMBP2.
- chr12:130,425,004–130,669,233, 3 genes, copy number 7–8: AC063926.3, AC063926.2, AC095350.1.
- chr15:19,878,555–23,182,049, 155 genes, copy number 7 (broad region; genes not listed).
- chr15:61,638,928–101,979,093, 1,045 genes, copy number 8 (broad region; genes not listed).
- chr22:16,857,619–16,934,003, 10 genes, copy number 7: ZNF402P, AC007064.2, MTND1P17, AC007064.1, AC006548.1, IGKV1OR22-5, IGKV2OR22-4, IGKV2OR22-3, IGKV3OR22-2, IGKV1OR22-1.
- chr22:17,787,649–18,024,561, 1 gene, copy number 8 (within-gene range 6–8): MICAL3.
- chr22:17,980,868–22,294,794, 258 genes, copy number 8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 725. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
